Gene-level copy-number profile of tumor specimen C3N-02185-01 from CPTAC case C3N-02185, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.9 years (22,613 days).
Specimen C3N-02185-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 47d2b1cf-13a3-4a09-bebb-75131bd623c1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02185-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/0d64714b-6326-4aec-a2cc-10b806750ab2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 10,259; copy number 2: 45,938; copy number 3: 2,159; copy number 7: 32.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr10:87,863,625–87,971,930, 3 genes: PTEN, AC063965.2, RPL11P3.
- chr13:48,303,744–48,599,436, 6 genes (within-gene range 0–1): RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP.
- chr14:18,634,955–18,637,421, 2 genes: CR383656.1, CR383656.12.
- chr15:28,679,405–28,682,252, 1 gene (within-gene range 0–1): AC055876.2.
- chr15:28,703,554–28,703,790, 1 gene (within-gene range 0–1): RN7SL719P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 32 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:126,325,454–128,220,803, 32 genes, copy number 7: AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226.

Autosomal genes at a single copy (total copy number 1): 9,652. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
